Somatic mutation profile of tumor specimen TCGA-B0-5693-01A (aliquot TCGA-B0-5693-01A-11D-1534-10) from TCGA case TCGA-B0-5693, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 47.0 years (17,177 days).
Specimen TCGA-B0-5693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c9097fe-1acc-491c-b2b5-f4fb53f396e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5693-11A (Solid Tissue Normal), aliquot TCGA-B0-5693-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fe2fadd-37a5-4844-874f-1d4c416925e4

The open-access MAF lists 37 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 23, Frame Shift Del 6, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.1124A>C p.E375A | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51997249; called by muse, mutect2, varscan2
- CATSPER1 | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 141/425 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.878); catalogued as COSV56413310; called by muse, mutect2, varscan2
- CCDC18 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.513); catalogued as COSV58147538; called by muse, mutect2, varscan2
- CCDC54 | c.934A>G p.N312D | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV53759787; called by muse, mutect2, varscan2
- CCDC91 | c.1113G>T p.K371N | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV60348214; called by mutect2, varscan2
- CDK12 | c.3298G>A p.D1100N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV70999434; called by muse, mutect2, varscan2
- CGGBP1 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.034); catalogued as COSV58851462, COSV58853025; called by muse, mutect2, varscan2
- CKS2 | c.200T>G p.L67R | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58686847; called by muse, mutect2, varscan2
- CPXM1 | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66046739; called by muse, mutect2, varscan2
- DYNC2H1 | c.12134A>G p.N4045S | Missense Mutation (SNP) | VAF 162/566 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1240773181, COSV62106236; called by muse, mutect2
- GJB6 | c.300C>A p.H100Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.675); catalogued as COSV53833498; called by muse, mutect2, varscan2
- HSPA8 | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV57086281; called by muse, mutect2, varscan2
- KANSL1 | c.2378C>G p.S793C | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.698); catalogued as COSV52273811; called by muse, mutect2, varscan2
- LRRC40 | c.1436T>G p.L479R | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63943354; called by muse, mutect2, varscan2
- MEN1 | c.1073del p.Y358Sfs*15 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as COSV53646564; called by mutect2, pindel, varscan2
- NHLRC2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV63749673; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2437G>T p.E813* (on ENST00000259318 / NM_001136562.3; = p.E1044* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 53/163 reads (33%) | catalogued as COSV52181142; called by muse, mutect2, varscan2
- PCDH15 | c.4241G>A p.R1414Q | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs866920137, COSV57268337; called by muse, mutect2, varscan2
- PCDH19 | c.3160del p.E1054Rfs*76 (on ENST00000373034 / NM_001184880.2; = p.E1006Rfs*76 on NM_020766.3) | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as COSV55258846, COSV99719541; called by mutect2, varscan2
- PNMA5 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV62626254; called by muse, mutect2
- PSMD11 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 133/409 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV55581036; called by muse, mutect2, varscan2
- TIMMDC1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 120/409 reads (29%) | catalogued as COSV51787995; called by muse, mutect2, varscan2
- TOR3A | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.444); catalogued as COSV61680827; called by muse, mutect2, varscan2
- TTN | c.97802A>G p.K32601R (on ENST00000591111; = p.K25177R on NM_003319.4) | Missense Mutation (SNP) | VAF 88/234 reads (38%) | PolyPhen benign (0.015); catalogued as rs1553493858, COSV60331576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP28 | c.1886T>G p.V629G | Missense Mutation (SNP) | VAF 21/421 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV50189684; called by muse, mutect2
- ZC3H18 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56324252, COSV56327915; called by muse, mutect2, varscan2
- ZNF236 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 30/505 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV53497193; called by muse, mutect2
- FAM91A1 | c.563del p.P188Lfs*20 | Frame Shift Del (DEL) | VAF 105/417 reads (25%) | called by mutect2, pindel, varscan2
- ITGAM | c.1588del p.D530Tfs*2 (on ENST00000648685 / NM_001145808.2; = p.D529Tfs*2 on NM_000632.4) | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1851del p.L617Ffs*25 | Frame Shift Del (DEL) | VAF 78/198 reads (39%) | called by mutect2, pindel, varscan2
- RABGAP1 | c.277_290del p.D93* | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- TGM7 | c.1950_1956delinsG p.I651_N652del | In Frame Del (DEL) | VAF 28/75 reads (37%) | called by pindel, varscan2*
- VHL | c.438dup p.I147Yfs*27 | Frame Shift Ins (INS) | VAF 67/227 reads (30%) | called by mutect2, pindel, varscan2
- ADCY1 | c.2283G>A p.T761= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs746675248, COSV52030091; called by muse, mutect2, varscan2
- FECH | c.504T>C p.P168= | Silent (SNP) | VAF 288/653 reads (44%) | catalogued as COSV50492664; called by muse, mutect2, varscan2
- UBQLN1 | c.1662C>G p.L554= | Silent (SNP) | VAF 147/487 reads (30%) | catalogued as COSV57409391; called by muse, mutect2, varscan2
- YTHDC2 | c.2646T>C p.A882= | Silent (SNP) | VAF 75/321 reads (23%) | catalogued as COSV50739214; called by muse, mutect2, varscan2
